CCDI case PBCICS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dbedb0b3-1a0e-46d4-b6d3-74c444825b04

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,206 days).

Biospecimens (3 samples)
- Sample 0DSWYO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSWYZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWZ6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
